Somatic mutation profile of tumor specimen TCGA-B5-A3FH-01A (aliquot TCGA-B5-A3FH-01A-11D-A19Y-09) from TCGA case TCGA-B5-A3FH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 74.5 years (27,221 days).
Specimen TCGA-B5-A3FH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e2ca4e9-8454-4adb-b15f-a3b6a52f5bea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A3FH-10A (Blood Derived Normal), aliquot TCGA-B5-A3FH-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6dc6358-830d-44fc-9796-2648b5dd79fd

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 19, Silent 15, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- PTEN | c.634+3_634+6del p.X212_splice | Splice Site (DEL) | VAF 10/18 reads (56%) | hotspot (GDC flag); called by mutect2, varscan2
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 17/24 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- ABHD16B | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1445655421, COSV99410549; called by muse, mutect2, varscan2
- AL645922.1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100190801; called by muse, mutect2, varscan2
- CHRNB1 | c.288C>A p.D96E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs1432288070, COSV53440948, COSV99548178; called by muse, mutect2, varscan2
- DSCAM | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as rs774341674, COSV68020548; called by muse, mutect2, varscan2
- HCK | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV52947070, COSV99393816; called by muse, mutect2, varscan2
- KDM6B | c.3732A>C p.E1244D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as COSV99640866; called by muse, mutect2, varscan2
- KMT2D | c.4549del p.E1517Rfs*4 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as COSV56427262; called by mutect2, pindel*, varscan2
- LRP1B | c.2897C>A p.T966N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1263088075, COSV101253753; called by muse, mutect2, varscan2
- NFKBIE | c.947A>T p.K316M (on ENST00000275015; = p.K177M on NM_004556.3) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99240955; called by muse, mutect2
- PALM | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs376337492, COSV99214345; called by muse, varscan2
- PLCD3 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1343317074, COSV100504126; called by muse, mutect2, varscan2
- PPP1R27 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs770386678, COSV57672276; called by muse, mutect2, varscan2
- SPG7 | c.1783G>A p.A595T (on ENST00000268704; = p.A602T on NM_003119.4) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs754771891, COSV99244671; called by muse, mutect2, varscan2
- STK38L | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV101198730; called by muse, mutect2
- SULT1A2 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs772334533, COSV57681222; called by muse, mutect2, varscan2
- TLCD4 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100930733; called by muse, mutect2, varscan2
- TPSG1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs757789922, COSV52353247; called by muse, varscan2
- TTC8 | c.1127G>T p.G376V (on ENST00000338104 / NM_001288781.1; = p.G360V on NM_144596.4) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100581118; called by muse, mutect2
- USP11 | c.1864C>T p.P622S (on ENST00000218348; = p.P579S on NM_001371072.1) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV99510739; called by muse, mutect2, varscan2
- WDR6 | c.3262G>A p.V1088M | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100556209; called by muse, mutect2, varscan2
- BTAF1 | c.4393dup p.Y1465Lfs*3 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- EXPH5 | c.5864del p.P1955Rfs*51 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- FOSL2 | c.532_534del p.E178del | In Frame Del (DEL) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- FRMD4A | c.1288_1291del p.D430Qfs*12 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- AL441992.2 | c.1440G>A p.V480= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100223416; called by muse, mutect2, varscan2
- ALDH7A1 | c.1527C>A p.G509= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101301996; called by muse, mutect2
- BCOR | c.4236C>G p.A1412= (on ENST00000378444 / NM_001123385.2; = p.A1378= on NM_017745.6) | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV100652998; called by muse, mutect2, varscan2
- CRYBA4 | c.330C>T p.F110= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs376978067; called by muse, mutect2, varscan2
- FLT1 | c.2184C>A p.V728= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99149513; called by muse, mutect2, varscan2
- MAST1 | c.1911C>T p.G637= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs762066400, COSV99262466; called by muse, mutect2, varscan2
- NCAM2 | c.2418G>A p.K806= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV99521716; called by muse, mutect2
- PRMT1 | c.42T>C p.F14= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV101212233; called by muse, mutect2, varscan2
- ROR2 | c.954C>T p.N318= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs553026289, COSV65216209; called by muse, mutect2, varscan2
- SLC12A2 | c.1347C>T p.F449= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs377735249; called by muse, mutect2, varscan2
- SMARCA4 | c.2142C>T p.V714= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs748567373, COSV100758217; ClinVar: likely benign; called by muse, mutect2, varscan2
- SP8 | c.123C>A p.S41= (on ENST00000361443 / NM_198956.4; = p.S59= on NM_182700.6) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs906782109, COSV100815282; called by muse, mutect2, varscan2
- SSRP1 | c.1260G>A p.A420= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1010600728, COSV53480821; called by muse, mutect2, varscan2
- TMEM150B | c.579C>T p.F193= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs774513528, COSV58593776; called by muse, mutect2, varscan2
- ZNF674 | c.1620C>A p.L540= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV101345023; called by muse, mutect2, varscan2
